Somatic mutation profile of tumor specimen C3N-05991-01 (aliquot CPT0378550006) from CPTAC case C3N-05991, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 28.7 years (10,474 days).
Specimen C3N-05991-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d36aa98e-6dd2-4541-826d-eb624925f188.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-05991-31 (Blood Derived Normal), aliquot CPT0378610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ecbd83d-2162-4789-a328-6803263f5efa

The open-access MAF lists 1,973 somatic variants for this specimen: 1,290 protein-altering or splice-affecting, 480 silent, 203 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,202, Silent 480, Intron 94, Nonsense Mutation 45, 3'UTR 38, RNA 34, Frame Shift Del 15, Splice Region 14, 5'UTR 14, 5'Flank 12, 3'Flank 11, Splice Site 8.

Variants (750 of 1,973; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 57/125 reads (46%) | catalogued as rs774824767, CM103536; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.9454C>T p.R3152* | Nonsense Mutation (SNP) | VAF 32/143 reads (22%) | catalogued as rs587783292, CM142031, COSV54124029; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKL5 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 97/104 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1555949009, COSV101184070, COSV66110788; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CHD2 | c.2425C>T p.R809* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as rs146691368; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 73/189 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- IRAK4 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377584435, CM078314; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ITGA2B | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 19/346 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214448436, CM093509; ClinVar: likely pathogenic; called by muse, mutect2
- MSH6 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 81/197 reads (41%) | catalogued as rs63750019, CM085563, COSV52275939; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2446C>T p.R816* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as rs886041347, CM971040, COSV62196183; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NOTCH1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 120/595 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1057523819, COSV53030190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PLA2G6 | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 47/481 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121908687, CM090726; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SETX | c.6407G>A p.R2136H | Missense Mutation (SNP) | VAF 34/419 reads (8%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.887); catalogued as rs121434378, CM041510, COSV56388997; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- SLC2A1 | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 114/284 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs267607059, CM0910158, COSV100996031; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 145/327 reads (44%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 138/345 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TTN | c.74371C>T p.R24791* (on ENST00000591111; = p.R17367* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 122/291 reads (42%) | catalogued as rs774411587, COSV59903609; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13164A>C p.K4388N | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs759333318; called by muse, mutect2
- ABCA2 | c.6799C>T p.R2267C (on ENST00000614293; = p.R2237C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/315 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV99687659; called by muse, mutect2
- ABHD17B | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 22/641 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.299); catalogued as rs1185912634; called by muse, mutect2
- AC011005.1 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.133); catalogued as rs956577956, COSV71956102; called by muse, mutect2
- AC011462.1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.319); catalogued as rs536540966, COSV54195750; called by muse, mutect2, varscan2
- AC069544.2 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766836506; called by muse, mutect2, varscan2
- AC073316.1 | n.197G>A | Splice Region (SNP) | VAF 68/231 reads (29%) | catalogued as rs745845333; called by muse, mutect2
- ACOT8 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs748013618, COSV54171573; called by muse, mutect2, varscan2
- ACSL6 | c.1286G>A p.R429Q (on ENST00000379240; = p.R454Q on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs1215418257, COSV99733529; called by muse, mutect2, varscan2
- ADAD1 | c.965T>G p.I322S | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV56642187; called by muse, mutect2, varscan2
- ADAMTS12 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201263969, COSV61281223; called by muse, mutect2, varscan2
- ADAMTS14 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs764571352; called by muse, mutect2, varscan2
- ADAMTS16 | c.3136C>T p.R1046C | Missense Mutation (SNP) | VAF 125/312 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764160416; called by muse, mutect2, varscan2
- ADAMTSL5 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs756561166; called by muse, mutect2, varscan2
- ADCK2 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 141/339 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs1214999246; called by muse, mutect2, varscan2
- ADGRB1 | c.2849C>T p.T950M | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1159814911, COSV60096398; called by muse, mutect2, varscan2
- ADGRB3 | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53235323; called by muse, mutect2, varscan2
- ADGRB3 | c.3290C>T p.A1097V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749140448, COSV53234890, COSV53245698; called by muse, mutect2, varscan2
- ADGRD1 | c.127T>A p.S43T | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV55442137; called by muse, mutect2, varscan2
- AGAP1 | c.2062G>A p.V688I (on ENST00000304032 / NM_001037131.3; = p.V635I on NM_014914.5) | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.194); catalogued as rs151161815; called by muse, mutect2, varscan2
- AGAP4 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1289763348, COSV101432651; called by muse, mutect2, varscan2
- AGT | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267598410; called by muse, mutect2, varscan2
- AJM1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1019039416; called by muse, mutect2, varscan2
- AK9 | c.5168C>T p.A1723V | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.448); catalogued as rs753059975, COSV69850273; called by muse, mutect2, varscan2
- AK9 | c.4204C>T p.R1402C | Missense Mutation (SNP) | VAF 95/264 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs1029844116; called by muse, mutect2, varscan2
- AKAP17A | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 146/391 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as rs765969002; called by muse, mutect2, varscan2
- AKAP9 | c.5734C>T p.R1912C (on ENST00000359028; = p.R1880C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/414 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as rs761946454, COSV62342900; called by muse, mutect2, varscan2
- AKNA | c.4171G>A p.D1391N | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs375161600, COSV56339047; called by muse, mutect2, varscan2
- ALB | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs774294755, COSV55738750, COSV55739357; called by muse, mutect2, varscan2
- ALCAM | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262196322; called by muse, mutect2
- ALOX12B | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs562084711, COSV59871674; called by muse, mutect2
- AMER3 | c.100A>G p.T34A | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100366723; called by muse, mutect2
- AMPD3 | c.1420C>T p.P474S (on ENST00000396553 / NM_001025389.2; = p.P483S on NM_000480.3) | Missense Mutation (SNP) | VAF 137/612 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67330361; called by muse, mutect2, varscan2
- ANKH | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 59/429 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs752084608; called by muse, mutect2, varscan2
- ANKRD18A | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1389538191, COSV68803410; called by muse, mutect2, varscan2
- ANO2 | c.2090+1G>A p.X697_splice (on ENST00000356134 / NM_001278597.3; = p.X701_splice on NM_001278596.3) | Splice Site (SNP) | VAF 50/135 reads (37%) | catalogued as rs369484425; called by muse, mutect2, varscan2
- ANO9 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs778954042, COSV100241290; called by muse, mutect2, varscan2
- ANPEP | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as rs746810178, COSV55590626; called by muse, mutect2, varscan2
- AOPEP | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1348609446, COSV104373614; called by muse, mutect2
- AP3B2 | c.3100A>G p.T1034A (on ENST00000261722; = p.T1028A on NM_004644.5) | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0.011); catalogued as rs1567252968; called by muse, mutect2
- APBA1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.012); catalogued as COSV55233482; called by muse, mutect2, varscan2
- APEX1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 83/284 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs367614890; called by muse, mutect2, varscan2
- APEX2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as rs749704346, COSV66624174; called by muse, mutect2, varscan2
- APLP2 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs778175330; called by muse, mutect2, varscan2
- APOBEC3C | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs576543647, COSV53325603; called by muse, mutect2, varscan2
- ARHGEF16 | c.428del p.G143Afs*3 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs775122856, COSV65683578; called by mutect2, pindel
- ARHGEF28 | c.5003G>A p.R1668H (on ENST00000426542; = p.R1694H on NM_001080479.2) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs887814001; called by muse, mutect2, varscan2
- ARHGEF33 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781162421, COSV67256589; called by muse, mutect2, varscan2
- ARID1B | c.2021A>G p.D674G | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51648090, COSV51656741; called by muse, mutect2, varscan2
- ARID3B | c.1442C>T p.S481L (on ENST00000622429 / NM_001307939.1; = p.S480L on NM_006465.4) | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as rs780954234; called by muse, mutect2, varscan2
- ARIH2 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs546937892; called by muse, mutect2
- ARPP21 | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV51807816; called by muse, mutect2, varscan2
- ASAP2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs757499704, COSV55635586; called by muse, mutect2, varscan2
- ASB15 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as rs758269356, COSV51926441; called by muse, mutect2, varscan2
- ASPHD1 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs1433020211, COSV58098898; called by muse, mutect2, varscan2
- ASTN1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.878); catalogued as COSV99922206; called by muse, mutect2, varscan2
- ATF3 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 38/287 reads (13%) | catalogued as rs756952643, COSV58378340; called by muse, mutect2, varscan2
- ATG4D | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as rs367877282; called by muse, mutect2, varscan2
- ATG4D | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.037); catalogued as rs368697131; called by muse, mutect2, varscan2
- ATG4D | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs1401127662, COSV57265064; called by muse, mutect2, varscan2
- ATP10A | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 103/365 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.394); catalogued as rs756690890; called by muse, mutect2, varscan2
- ATP10B | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 122/266 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs192248100; called by muse, mutect2, varscan2
- ATP8A2 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 58/77 reads (75%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs754599384; called by muse, mutect2, varscan2
- ATP8B3 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 69/134 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372598351; called by muse, mutect2, varscan2
- ATRN | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 103/214 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0.227); catalogued as rs767574295, COSV53535586; called by muse, mutect2, varscan2
- ATRNL1 | c.1160T>G p.V387G | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV61801729; called by muse, mutect2
- ATRX | c.4510C>T p.R1504* | Nonsense Mutation (SNP) | VAF 114/126 reads (90%) | catalogued as COSV64872902; called by muse, varscan2
- B3GNT2 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.632); catalogued as rs201194611; called by muse, mutect2
- B4GALNT3 | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201094958; called by muse, mutect2, varscan2
- B4GALT2 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs199591624, COSV58843444; called by muse, mutect2, varscan2
- BAIAP2L1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs375051431; called by muse, mutect2, varscan2
- BEST3 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 73/175 reads (42%) | catalogued as COSV99876052; called by muse, mutect2, varscan2
- BET1L | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as rs749580292, COSV57315175; called by muse, mutect2, varscan2
- BLVRB | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs200026690; called by muse, mutect2, varscan2
- BPI | c.254A>G p.Y85C (on ENST00000262865; = p.Y81C on NM_001725.3) | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV53404280; called by muse, mutect2, varscan2
- BRD1 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 58/133 reads (44%) | catalogued as COSV53456078, COSV99349814; called by muse, mutect2, varscan2
- BRSK2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV57546056; called by muse, mutect2, varscan2
- BSPRY | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs967500212; called by muse, mutect2, varscan2
- C11orf52 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 79/210 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs782072534, COSV99585555; called by muse, mutect2, varscan2
- C11orf53 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs1163321920; called by muse, mutect2
- C11orf68 | c.257A>G p.Y86C (on ENST00000530188; = p.Y127C on NM_031450.4) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1246972968; called by muse, mutect2, varscan2
- C12orf29 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1372893314, COSV58351578; called by muse, mutect2
- C20orf194 | c.3497A>C p.Q1166P | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.439); catalogued as rs1452535535; called by muse, mutect2
- C3 | c.2996G>A p.R999Q | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55578014, COSV99837288; called by muse, mutect2, varscan2
- C4orf54 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as rs539120754; called by muse, mutect2, varscan2
- C5AR2 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 110/236 reads (47%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.62); catalogued as rs779835516, COSV99953806; called by muse, mutect2, varscan2
- CA1 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 100/370 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs769195145; called by muse, mutect2, varscan2
- CACHD1 | c.3095A>G p.D1032G | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV51562310; called by muse, mutect2, varscan2
- CACNA1B | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769225657, COSV99494980; called by muse, mutect2, varscan2
- CALHM3 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs778497712; called by muse, mutect2, varscan2
- CALHM5 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as rs763170051; called by muse, mutect2, varscan2
- CAMK1G | c.1291T>C p.S431P | Missense Mutation (SNP) | VAF 19/328 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.091); catalogued as rs966818017; called by muse, mutect2
- CAMTA2 | c.2453C>T p.S818L | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs376704366; called by muse, mutect2, varscan2
- CAMTA2 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as rs778329985; called by muse, mutect2, varscan2
- CARD6 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs749841915, COSV54565169; called by muse, mutect2, varscan2
- CBX2 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs782217625; called by muse, mutect2, varscan2
- CCDC114 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs200690633; called by muse, mutect2, varscan2
- CCDC18 | c.3592C>T p.R1198C (on ENST00000343253 / NM_001306076.1; = p.R1199C on NM_206886.4) | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs183806092; called by muse, mutect2, varscan2
- CCDC186 | c.2016G>T p.Q672H | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100991103; called by muse, mutect2, varscan2
- CCDC22 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs782461322; called by muse, mutect2
- CCDC24 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs776834078; called by muse, mutect2
- CCDC89 | c.128A>G p.D43G | Missense Mutation (SNP) | VAF 60/410 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1188022792; called by muse, mutect2, varscan2
- CCN4 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs778202911, COSV51533217; called by muse, mutect2, varscan2
- CCNB3 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 65/78 reads (83%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs781972354, COSV52076512; called by muse, mutect2, varscan2
- CD163 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs762652679, COSV100776170; called by muse, mutect2, varscan2
- CD1B | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs766313542; called by muse, mutect2, varscan2
- CD72 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 16/517 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV52412094; called by muse, mutect2
- CDC26 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs770825288; called by muse, mutect2, varscan2
- CDH1 | c.2381T>C p.V794A | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1447544874; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH11 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV51775944; called by muse, mutect2
- CELSR2 | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 105/246 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as rs372546163; called by muse, mutect2, varscan2
- CEP131 | c.2789G>A p.R930Q (on ENST00000269392 / NM_001319228.2; = p.R927Q on NM_014984.4) | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as rs577173678; called by muse, mutect2, varscan2
- CEP57 | c.785dup p.K263Efs*11 | Frame Shift Ins (INS) | VAF 83/232 reads (36%) | catalogued as rs762013265; called by mutect2, varscan2
- CEP72 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs538033713, COSV53796761; called by muse, mutect2, varscan2
- CERS1 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); catalogued as rs769809173; called by muse, mutect2, varscan2
- CES3 | c.1606G>A p.G536R | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as rs149091298, COSV57595142; called by muse, mutect2
- CFAP65 | c.2956G>A p.V986I | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs750628275; called by muse, mutect2
- CHD4 | c.2828G>A p.R943Q (on ENST00000357008 / NM_001363606.2; = p.R956Q on NM_001273.5) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV58896255; called by muse, mutect2
- CHMP1A | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as rs960075965; called by muse, mutect2, varscan2
- CHPF2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 123/310 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0.262); catalogued as rs372526283; called by muse, mutect2, varscan2
- CHRNB2 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs763142542; called by muse, mutect2
- CHST3 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs767508669, COSV100910368; called by muse, mutect2
- CHST4 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144351846; called by muse, mutect2, varscan2
- CLCNKB | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 77/529 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs200634290; called by muse, mutect2, varscan2
- CLEC18C | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 195/911 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.137); catalogued as rs137932955; called by muse, mutect2, varscan2
- CLEC3B | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV56110485; called by muse, varscan2
- CLEC3B | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs1299330131, COSV56110517; called by muse, varscan2
- CLTCL1 | c.3494G>A p.R1165H | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs372594770; called by muse, mutect2
- CNN3 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as rs1032906772; called by muse, mutect2, varscan2
- CNOT6L | c.917C>T p.A306V (on ENST00000504123 / NM_001286790.2; = p.A301V on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1481358623, COSV53698148; called by muse, mutect2
- CNTNAP1 | c.3458G>A p.R1153Q | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs940735813; called by muse, mutect2, varscan2
- CNTNAP4 | c.1466G>A p.G489D | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs1366189550, COSV100273440; called by muse, mutect2
- COBL | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 71/351 reads (20%) | catalogued as rs762511272; called by muse, mutect2, varscan2
- COL20A1 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 71/216 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.553); catalogued as rs772983475; called by muse, mutect2, varscan2
- COL27A1 | c.2606T>C p.F869S | Missense Mutation (SNP) | VAF 21/367 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750826790; called by muse, mutect2
- COL5A1 | c.2278G>A p.G760R | Missense Mutation (SNP) | VAF 90/309 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376035050, COSV65666647; called by muse, mutect2, varscan2
- COL6A1 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 169/555 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200835287, COSV62615768; ClinVar: likely benign; called by muse, mutect2, varscan2
- COX15 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 71/428 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.035); catalogued as COSV50012451, COSV50013046; called by muse, mutect2, varscan2
- CPA1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as rs1303947345, COSV50569075, COSV99163252; called by muse, mutect2
- CPT1A | c.1691C>T p.T564M | Missense Mutation (SNP) | VAF 128/272 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.891); catalogued as rs117607023; called by muse, mutect2, varscan2
- CRACD | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 99/219 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs977713314; called by muse, mutect2, varscan2
- CROCC | c.2663C>T p.A888V | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.739); catalogued as rs1375352560; called by muse, mutect2, varscan2
- CS | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs201492283, COSV100673294; called by muse, mutect2, varscan2
- CSMD1 | c.10469C>T p.A3490V (on ENST00000520002; = p.A3489V on NM_033225.6) | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755659271, COSV100153008; called by muse, mutect2, varscan2
- CSMD1 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 75/318 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs753420644, COSV101221787, COSV68229471; called by muse, mutect2, varscan2
- CSMD2 | c.8719A>G p.S2907G | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as rs893327722; called by muse, mutect2, varscan2
- CSMD2 | c.4600G>A p.A1534T | Missense Mutation (SNP) | VAF 105/221 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752544898, COSV53887300; called by muse, mutect2, varscan2
- CSPG4 | c.4675C>T p.R1559C | Missense Mutation (SNP) | VAF 84/165 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs557064196, COSV57902024; called by muse, mutect2, varscan2
- CSPG4 | c.3101G>A p.R1034Q | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755806843, COSV57893023; called by muse, mutect2, varscan2
- CTNNB1 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62688225; called by muse, mutect2, varscan2
- CTSH | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 34/323 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1158014802, COSV54984742; called by muse, mutect2, varscan2
- CUBN | c.1028A>G p.D343G | Missense Mutation (SNP) | VAF 49/352 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV64712752; called by muse, mutect2, varscan2
- CUL2 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1347538705, COSV66078403, COSV66079131; called by muse, mutect2
- CUL9 | c.5252G>A p.R1751Q | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.687); catalogued as rs201133006; called by muse, mutect2, varscan2
- CYFIP2 | c.2383C>T p.R795C (on ENST00000616178 / NM_001291722.2; = p.R770C on NM_014376.4) | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs769807842; called by muse, mutect2, varscan2
- CYP26C1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.876); catalogued as rs905517880; called by muse, mutect2
- CYP27C1 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.394); catalogued as rs1209248467, COSV58867548; called by muse, mutect2, varscan2
- CYP7A1 | c.1405C>T p.L469F | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.324); catalogued as COSV56963744; called by muse, mutect2, varscan2
- D2HGDH | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 103/249 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs1374662899; called by muse, mutect2, varscan2
- DACT2 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 105/264 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342485076; called by muse, mutect2, varscan2
- DCAF1 | c.4055G>A p.R1352Q | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1264819709, COSV100244605, COSV60040781; called by muse, mutect2
- DCHS2 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1374169718; called by muse, mutect2, varscan2
- DDC | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 95/507 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs752108612, COSV63564210, COSV63568522; called by muse, mutect2, varscan2
- DDHD1 | c.1607G>A p.R536Q (on ENST00000323669; = p.R733Q on NM_030637.3) | Missense Mutation (SNP) | VAF 112/266 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs201550288, COSV60361232; called by muse, mutect2, varscan2
- DENND4B | c.22del p.R8Gfs*8 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs755611865; called by mutect2, pindel, varscan2
- DGCR2 | c.1216T>G p.F406V | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as COSV99593532; called by muse, mutect2
- DGKI | c.2752G>A p.V918M | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs753942158, COSV55934610; called by muse, mutect2, varscan2
- DIO2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs775882497; called by muse, mutect2, varscan2
- DIP2A | c.3574G>A p.A1192T | Missense Mutation (SNP) | VAF 90/178 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.448); catalogued as rs749572406, COSV100596325; called by muse, mutect2, varscan2
- DMBT1 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV57540556; called by muse, mutect2
- DNAH1 | c.11950C>T p.R3984W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs750536856; called by muse, mutect2, varscan2
- DNAH10 | c.11149del p.A3717Pfs*13 (on ENST00000409039; = p.A3656Pfs*13 on NM_207437.3) | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | catalogued as COSV101291861; called by mutect2, pindel, varscan2
- DNAH17 | c.5567C>T p.T1856M | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201579518; called by muse, mutect2, varscan2
- DNAH2 | c.2935C>T p.R979C | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs778952974; called by muse, mutect2, varscan2
- DNAH3 | c.10052A>G p.D3351G | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs778346996; called by muse, mutect2, varscan2
- DNAH6 | c.7705C>T p.R2569C | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1428887330; called by muse, mutect2, varscan2
- DNAH9 | c.5432G>A p.R1811H | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772276258, COSV99302993; called by muse, mutect2, varscan2
- DNLZ | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs548961606, COSV52517273, COSV99395979; called by muse, mutect2, varscan2
- DOCK3 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433479340; called by muse, mutect2, varscan2
- DOCK4 | c.1309A>C p.T437P | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV70323719; called by muse, mutect2, varscan2
- DOCK8 | c.2654G>A p.R885H | Missense Mutation (SNP) | VAF 58/626 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs755881130, COSV66617287; called by muse, mutect2
- DOK1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT tolerated (0.83); PolyPhen benign (0.012); catalogued as COSV51212237; called by muse, mutect2
- DOK7 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 217/505 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as rs571769859, CM108746, COSV60773455; called by muse, mutect2, varscan2
- DPYSL4 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs751981237; called by muse, mutect2, varscan2
- DRC7 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749631550; called by muse, mutect2, varscan2
- DSC2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 113/452 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs727504578, CM102850, COSV104378010; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAML1 | c.2626C>T p.R876W (on ENST00000321322; = p.R816W on NM_020693.4) | Missense Mutation (SNP) | VAF 200/474 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as rs756267742, COSV58389549; called by muse, mutect2, varscan2
- DSG3 | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs200927289; called by muse, mutect2, varscan2
- DSP | c.5834G>A p.R1945H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs759516161, COSV65794183; called by muse, mutect2
- DSP | c.8554G>A p.A2852T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV60939195; called by muse, mutect2, varscan2
- DTX1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.392); catalogued as rs754315228; called by muse, varscan2
- DUOX1 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368147950; called by muse, mutect2, varscan2
- EBF4 | c.739C>T p.R247C (on ENST00000609451; = p.R243C on NM_001110514.1) | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1185778042; called by muse, mutect2, varscan2
- EBPL | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757958154; called by muse, mutect2, varscan2
- EDF1 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 143/540 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1172475396; called by muse, mutect2, varscan2
- EFCAB8 | c.1976A>G p.D659G | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1445635135; called by muse, mutect2, varscan2
- EIF2A | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.156); catalogued as rs771020114; called by muse, mutect2, varscan2
- EIF3E | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1451505628; called by muse, mutect2
- EIF4E2 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 77/198 reads (39%) | catalogued as COSV51471786; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs377378858, COSV57516280; called by muse, mutect2, varscan2
- ELF3 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs41270965, COSV62840440; called by muse, mutect2, varscan2
- EOGT | c.420G>A p.T140= | Splice Region (SNP) | VAF 24/192 reads (13%) | catalogued as rs748425624; called by muse, mutect2, varscan2
- EPHB4 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs201096509; called by muse, mutect2, varscan2
- EPHB6 | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 91/335 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs867659854, COSV100844464; called by muse, mutect2, varscan2
- EPN3 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 117/261 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs955884638; called by muse, mutect2, varscan2
- ERAS | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs782090794, COSV54432708, COSV99504862; called by muse, mutect2, varscan2
- ERCC4 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs751782722, COSV61312243; called by muse, mutect2, varscan2
- ERFE | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs1029767238, COSV54517779; called by muse, mutect2
- ERG | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 197/362 reads (54%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.731); catalogued as rs542019196, COSV55736057; called by muse, mutect2, varscan2
- ESPN | c.2061+6C>T | Splice Region (SNP) | VAF 72/521 reads (14%) | catalogued as rs755511480; called by muse, varscan2
- EVI5L | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs778590587, COSV54485629; called by muse, mutect2, varscan2
- EVPL | c.5270G>A p.R1757H | Missense Mutation (SNP) | VAF 91/235 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs1315113869, COSV56914909; called by muse, mutect2, varscan2
- EXOC8 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1558357784, COSV99150197; called by muse, mutect2, varscan2
- EXTL3 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 156/573 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs775364911; called by muse, mutect2, varscan2
- F10 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs777379687, COSV100979270; called by muse, varscan2
- F5 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs776229645, COSV100889135; called by muse, mutect2
- FAM110B | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 66/304 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355222894; called by muse, mutect2, varscan2
- FAM193A | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 111/266 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs758641625; called by muse, mutect2, varscan2
- FAM83H | c.2176G>A p.V726M | Missense Mutation (SNP) | VAF 214/547 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1293130871; called by muse, mutect2, varscan2
- FAM9B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.75); catalogued as COSV59119225; called by muse, mutect2, varscan2
- FAT1 | c.13757C>T p.T4586M | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376922855; called by muse, mutect2, varscan2
- FBRSL1 | c.2698G>A p.G900S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.972); catalogued as COSV55517994; called by mutect2, varscan2
- FBXL6 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs548024038, COSV57354162; called by muse, mutect2, varscan2
- FBXO11 | c.1139G>A p.R380Q (on ENST00000403359 / NM_001190274.2; = p.R296Q on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/171 reads (54%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.863); catalogued as rs551056796, COSV57023042; called by muse, mutect2, varscan2
- FBXO39 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200419578; called by muse, mutect2, varscan2
- FBXO7 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 114/423 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs112660869, COSV56682734; called by muse, mutect2, varscan2
- FCGBP | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs777323088; called by muse, mutect2, varscan2
- FCRL2 | c.754A>C p.T252P | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV100829955; called by muse, mutect2, varscan2
- FDXR | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 134/364 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302990152; called by muse, mutect2, varscan2
- FERMT2 | c.455dup p.K153Efs*5 | Frame Shift Ins (INS) | VAF 46/110 reads (42%) | catalogued as rs766229731, COSV58404966; called by mutect2, varscan2
- FGFR1OP2 | c.401A>G p.D134G | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.099); catalogued as rs755880696; called by muse, mutect2, varscan2
- FHOD1 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1159287570, COSV99263882; called by muse, mutect2
- FILIP1L | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 106/285 reads (37%) | catalogued as rs757041273; called by muse, mutect2, varscan2
- FITM1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 103/269 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs150217465; called by muse, mutect2, varscan2
- FLNB | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 116/261 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201165196, COSV55887840; called by muse, mutect2, varscan2
- FLNC | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 105/415 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1554396410, COSV100367578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT4 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs780661773, COSV56104523; called by muse, mutect2, varscan2
- FMO4 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 20/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147680748; called by muse, mutect2
- FMOD | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.431); catalogued as rs772265764, COSV61609968; called by muse, mutect2, varscan2
- FNDC3B | c.2146G>A p.V716I | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as rs371384228; called by muse, mutect2, varscan2
- FRAS1 | c.6376C>T p.R2126C | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs779986441; called by muse, mutect2, varscan2
- FRMD4A | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.062); catalogued as rs761744380, COSV62267514; called by muse, mutect2, varscan2
- FUCA2 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 64/118 reads (54%) | catalogued as rs1034334965, COSV50019785; called by muse, mutect2, varscan2
- FUT7 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 121/486 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as rs773909121, COSV55807740; called by muse, mutect2, varscan2
- GAA | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs770021831, COSV100162997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABPB2 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762312179; called by muse, mutect2
- GBP6 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 87/265 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs141648455; called by muse, mutect2
- GEN1 | c.1482A>C p.K494N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV58056081; called by muse, mutect2
- GGCX | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 185/449 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142918177, COSV99289925; called by muse, mutect2, varscan2
- GLB1 | c.1915G>A p.V639M | Missense Mutation (SNP) | VAF 157/408 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.486); catalogued as rs1222326938, COSV100257687; called by muse, mutect2, varscan2
- GLDC | c.1871C>T p.A624V | Missense Mutation (SNP) | VAF 230/800 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs779980470; called by muse, mutect2, varscan2
- GLI3 | c.2822C>T p.P941L | Missense Mutation (SNP) | VAF 226/791 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1327594220; called by muse, mutect2, varscan2
- GMIP | c.2876C>T p.P959L | Missense Mutation (SNP) | VAF 105/230 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs200584353, COSV52555352; called by muse, mutect2, varscan2
- GOLGA2 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.198); catalogued as rs777044759, COSV57851284; called by muse, mutect2, varscan2
- GOLGA3 | c.4142C>T p.T1381M | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs749482676; called by muse, mutect2, varscan2
- GPR137 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1197762978, COSV57402073; called by muse, mutect2, varscan2
- GPR137 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 78/528 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV57402153; called by muse, mutect2, varscan2
- GPR158 | c.3116A>C p.N1039T | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.177); catalogued as COSV66267951; called by muse, mutect2
- GPR161 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.197); catalogued as rs776855110, COSV54788700; called by muse, mutect2
- GPR83 | c.713A>C p.Y238S | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99703649; called by muse, mutect2, varscan2
- GPT2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs1205102812, COSV60840409; called by muse, mutect2
- GRAMD1C | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 110/251 reads (44%) | catalogued as rs897211852, COSV63984591; called by muse, mutect2, varscan2
- GRID1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV60024937; called by muse, mutect2
- GRIN3A | c.2205A>C p.K735N | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554915219; called by muse, mutect2
- GRIP2 | c.1394G>A p.G465D (on ENST00000619221; = p.G368D on NM_001080423.4) | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.462); catalogued as COSV56119612; called by muse, varscan2
- GRM3 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 16/116 reads (14%) | catalogued as rs891435292, COSV64467524; called by muse, mutect2, varscan2
- GSG1 | c.925G>A p.V309M (on ENST00000651961 / NM_001080555.4; = p.V273M on NM_153823.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs369212516; called by muse, mutect2, varscan2
- HADHA | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 104/288 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs761474139, COSV66106829; called by muse, mutect2, varscan2
- HAX1 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 162/343 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1170911395; called by muse, mutect2, varscan2
- HDHD3 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746796130; called by muse, mutect2, varscan2
- HEATR5A | c.2587G>A p.G863R | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs369224778; called by muse, mutect2, varscan2
- HECA | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760164332, COSV62768949; called by muse, mutect2, varscan2
- HELB | c.2977G>A p.A993T | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs774078070, COSV56073993; called by muse, mutect2, varscan2
- HELZ2 | c.6616del p.R2206Vfs*29 (on ENST00000467148 / NM_001037335.2; = p.R1637Vfs*29 on NM_033405.3) | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs745497383, COSV101427649; called by mutect2, varscan2
- HERC2 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1465401212, COSV55331317, COSV99876938; called by muse, mutect2
- HFM1 | c.4163del p.N1388Tfs*37 | Frame Shift Del (DEL) | VAF 19/44 reads (43%) | catalogued as rs759278255; called by mutect2, pindel, varscan2
- HIVEP1 | c.1711T>C p.S571P | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV101045923; called by muse, mutect2, varscan2
- HMCN1 | c.6730C>T p.R2244* | Nonsense Mutation (SNP) | VAF 33/232 reads (14%) | catalogued as rs373249075, COSV54909354; called by muse, mutect2, varscan2
- HMGB4 | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53918110; called by muse, mutect2, varscan2
- HMGCR | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1277575286; called by muse, mutect2, varscan2
- HNRNPM | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 307/682 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs1317748482; called by muse, mutect2, varscan2
- HS3ST1 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277515643; called by muse, varscan2
- HS3ST2 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 30/266 reads (11%) | catalogued as rs773697928, COSV54463215, COSV54466823; called by mutect2, varscan2
- HSF1 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs781968705, COSV68821956; called by muse, mutect2, varscan2
- HTRA3 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.531); catalogued as rs772344245, COSV56471387; called by muse, mutect2, varscan2
- HTT | c.6593C>T p.P2198L | Missense Mutation (SNP) | VAF 134/296 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs777249004; called by muse, mutect2
- IFNA10 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV53330728; called by muse, mutect2
- IGFALS | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 51/589 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs750178700; called by muse, mutect2
- IGHE | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 115/314 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.366); catalogued as rs370158500; called by muse, mutect2, varscan2
- IGHMBP2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 153/351 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs771485988; called by muse, mutect2, varscan2
- IGLV4-3 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as rs375927393; called by muse, mutect2, varscan2
- IGSF22 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as rs747796344; called by muse, mutect2
- IGSF8 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 45/351 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as rs145403328, COSV100081599; called by muse, mutect2, varscan2
- IL6ST | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763726030; called by muse, mutect2, varscan2
- ILVBL | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.436); catalogued as rs139501555; called by muse, mutect2, varscan2
- INPP5E | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.172); catalogued as rs775094328; called by muse, mutect2, varscan2
- INSIG2 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749320625, COSV55521984; called by muse, mutect2, varscan2
- INTS1 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 111/418 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs12667324, COSV104431336; called by muse, mutect2, varscan2
- INTS9 | c.1936C>T p.R646* | Nonsense Mutation (SNP) | VAF 89/463 reads (19%) | catalogued as rs150431221; called by muse, mutect2, varscan2
- IRAK3 | c.536T>C p.V179A | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54162674; called by muse, mutect2, varscan2
- IRS1 | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.854); catalogued as rs757021553, COSV59341695; called by muse, mutect2, varscan2
- ISL2 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV51958082; called by muse, mutect2, varscan2
- ITGB2 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs1482665972; called by muse, varscan2
- ITGB4 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as rs752599095, COSV52322640; called by muse, mutect2, varscan2
- ITPK1 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs768335687, COSV50896261; called by muse, mutect2, varscan2
- ITPR3 | c.4432G>A p.A1478T | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs763726545, COSV100966979; called by muse, mutect2, varscan2
- KALRN | c.7763G>A p.R2588H (on ENST00000360013 / NM_001024660.4; = p.R891H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.997); catalogued as rs374214808; called by muse, mutect2, varscan2
- KBTBD11 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1189688455; called by mutect2, varscan2
- KCNK4 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1198390698; called by muse, mutect2, varscan2
- KCNS2 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 51/454 reads (11%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.446); catalogued as rs1488567981; called by muse, mutect2, varscan2
- KCNV2 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 174/566 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377667539, CM162525, COSV66056902; called by muse, mutect2, varscan2
- KCTD14 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs77687067, COSV100779924; called by muse, mutect2, varscan2
- KHDC3L | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 166/416 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV64869234; called by muse, mutect2, varscan2
- KHSRP | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs759174783; called by muse, mutect2, varscan2
- KIAA1549 | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373550190; called by muse, mutect2, varscan2
- KIDINS220 | c.2701C>T p.R901W | Missense Mutation (SNP) | VAF 83/148 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs372110208; called by muse, mutect2, varscan2
- KIF20B | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as rs368664005; called by muse, mutect2, varscan2
- KIF23 | c.2796+8A>G | Splice Region (SNP) | VAF 12/198 reads (6%) | catalogued as rs1056018219; called by muse, mutect2
- KIF2B | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs753464095, COSV52127156; called by muse, mutect2, varscan2
- KIFC2 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1166106106; called by muse, mutect2, varscan2
- KIRREL1 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1479642415, COSV100779880; called by muse, mutect2, varscan2
- KLHDC4 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 111/254 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751000594, COSV54507827; called by muse, mutect2, varscan2
- KLHL20 | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs754888725; called by muse, mutect2, varscan2
- KPNB1 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs761508578, COSV51597541; called by muse, mutect2
- KRBA1 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770504668; called by muse, mutect2, varscan2
- KRT14 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs139800658; called by muse, mutect2, varscan2
- KRT34 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs767269385, COSV67449159; called by muse, mutect2, varscan2
- KRT34 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs139913573, COSV101222525; called by muse, varscan2
- KRT35 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs769662906, COSV55843983; called by muse, mutect2
- KRT78 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 53/356 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV58851226; called by muse, mutect2, varscan2
- KRTAP4-12 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs759767600, COSV67457797; called by muse, mutect2, varscan2
- KRTAP4-9 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as rs756953992; called by muse, mutect2
- KRTCAP3 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs758117368; called by muse, mutect2, varscan2
- LACTBL1 | c.436C>T p.R146C (on ENST00000618559; = p.R191C on NM_001289974.2) | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1479731987, COSV70777283; called by muse, varscan2
- LAMA5 | c.5542G>A p.G1848S | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372436992; called by muse, mutect2, varscan2
- LAMB2 | c.2882C>T p.T961M | Missense Mutation (SNP) | VAF 50/628 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs764009381, COSV59737466; called by muse, mutect2
- LARGE2 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs372844613; called by muse, mutect2, varscan2
- LCK | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 163/417 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1405031975, COSV60739531; called by muse, mutect2, varscan2
- LCT | c.1274C>T p.T425M | Missense Mutation (SNP) | VAF 93/339 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748907176, COSV51543639; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs375447132; called by muse, mutect2, varscan2
- LMLN2 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 76/151 reads (50%) | catalogued as rs764530848; called by muse, mutect2, varscan2
- LRFN2 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.124); catalogued as COSV57824422; called by muse, mutect2, varscan2
- LRIG2 | c.2221C>T p.R741* | Nonsense Mutation (SNP) | VAF 129/313 reads (41%) | catalogued as rs767815417; called by muse, mutect2, varscan2
- LRP1 | c.3076C>T p.R1026C | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54510175; called by muse, mutect2
- LRP1 | c.3901G>A p.A1301T | Missense Mutation (SNP) | VAF 32/519 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV54509894; called by muse, mutect2
- LRP12 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as rs202010679, COSV52632601; called by muse, mutect2
- LRRC14 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 112/501 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1457231623, COSV52882225; called by muse, mutect2, varscan2
- LRRC20 | c.488T>C p.I163T (on ENST00000355790 / NM_207119.3; = p.I107T on NM_018205.4) | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs1019484840; called by muse, mutect2, varscan2
- LRRC41 | c.2282G>A p.R761H | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); catalogued as rs780864615, COSV58439324; called by muse, mutect2, varscan2
- LRRC8E | c.570G>A p.M190I | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs767961070; called by muse, mutect2, varscan2
- LTA4H | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759388190, COSV57382450; called by muse, mutect2
- LTV1 | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as rs145954398; called by muse, mutect2, varscan2
- LUC7L | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.921); catalogued as rs1429219977, COSV53461108; called by muse, mutect2
- LYPD2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 44/476 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs867619325; called by muse, mutect2
- MACF1 | c.19621C>T p.R6541* (on ENST00000372915; = p.R4586* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 21/304 reads (7%) | catalogued as COSV57133543; called by muse, mutect2
- MAFG | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.368); catalogued as rs373186039; called by muse, mutect2, varscan2
- MAFK | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 130/453 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs1437310453; called by muse, mutect2, varscan2
- MAG | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 57/77 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757733728, COSV62698732; called by muse, mutect2, varscan2
- MAGI3 | c.3649C>T p.R1217* | Nonsense Mutation (SNP) | VAF 80/185 reads (43%) | catalogued as rs765382649; called by muse, mutect2, varscan2
- MAMDC4 | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 41/232 reads (18%) | catalogued as rs766190024, COSV56034089; called by muse, mutect2, varscan2
- MAP1B | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.997); catalogued as rs747897650, COSV57104729, COSV57107029; called by muse, mutect2, varscan2
- MAP3K9 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1483217886, COSV67122223; called by muse, mutect2, varscan2
- MARK4 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs200016116; called by muse, mutect2, varscan2
- MASP2 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376909147; called by muse, mutect2, varscan2
- MASP2 | c.1256C>T p.T419M | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.104); catalogued as rs201988936; called by muse, mutect2, varscan2
- MBL2 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs200416222, COSV64759338; called by muse, mutect2, varscan2
- MCF2L2 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs529572628, COSV61054446; called by muse, mutect2, varscan2
- MDN1 | c.5416C>T p.R1806C | Missense Mutation (SNP) | VAF 122/256 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.428); catalogued as rs748372187, COSV101021275; called by muse, mutect2, varscan2
- MED11 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs1248812705; called by muse, mutect2
- MED13L | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 140/316 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.03); catalogued as rs201172345; called by muse, mutect2, varscan2
- MED25 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 87/167 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs368059409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEGF6 | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs542675069; called by muse, mutect2, varscan2
- MICOS13 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs746370938; called by muse, mutect2, varscan2
- MKI67 | c.8461A>G p.T2821A | Missense Mutation (SNP) | VAF 145/337 reads (43%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.966); catalogued as rs776877138; called by muse, mutect2, varscan2
- MKS1 | c.515+8C>T | Splice Region (SNP) | VAF 131/428 reads (31%) | catalogued as rs376823839; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MKX | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs868476736, COSV101008500; called by muse, mutect2
- MMP17 | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs534877096, COSV62178548; called by muse, mutect2, varscan2
- MMP2 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 170/384 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs368282133; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 44/182 reads (24%) | catalogued as rs755830405; called by mutect2, varscan2
- MORC2 | c.2942G>A p.R981H (on ENST00000397641 / NM_001303256.3; = p.R919H on NM_014941.3) | Missense Mutation (SNP) | VAF 22/506 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs901120411, COSV53199173; called by muse, mutect2
- MORC3 | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1458803310; called by muse, mutect2, varscan2
- MORN1 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs764700581; called by muse, mutect2, varscan2
- MPDZ | c.1771G>A p.G591R | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs775614513, COSV100060869; called by muse, mutect2, varscan2
- MROH2B | c.4141G>A p.V1381M | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV68182568; called by muse, mutect2, varscan2
- MRPL38 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs371715586; called by muse, mutect2, varscan2
- MRTFA | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); catalogued as rs373666097, COSV62933025, COSV62935045; called by muse, mutect2, varscan2
- MSL1 | c.1304G>A p.R435H (on ENST00000398532 / NM_001365919.1; = p.R172H on NM_001012241.2) | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.106); catalogued as rs201593396; called by muse, mutect2, varscan2
- MTTP | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 116/238 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs369453726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.19823C>T p.S6608L | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs746016038, COSV67445814, COSV67466930; called by muse, mutect2, varscan2
- MUC5B | c.126C>T p.G42= | Splice Region (SNP) | VAF 12/112 reads (11%) | catalogued as rs761751705, COSV71592186; called by muse, mutect2, varscan2
- MUSK | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV51879460; called by muse, mutect2, varscan2
- MYADML2 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1320525638; called by muse, mutect2
- MYLK | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 112/243 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as rs1485918605, COSV60615594; called by muse, mutect2, varscan2
- MYO1D | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201799480; called by muse, mutect2, varscan2
- MYO1E | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 48/385 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1178412708, COSV99896840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1F | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 32/221 reads (14%) | catalogued as COSV57799431; called by muse, mutect2, varscan2
- MYO3A | c.2718C>T p.G906= | Splice Region (SNP) | VAF 42/329 reads (13%) | catalogued as rs1239496761, COSV56331480; called by muse, mutect2, varscan2
- MYO5A | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 178/398 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs375511929; called by muse, mutect2, varscan2
- MYO5A | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 64/417 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1472832846; called by muse, mutect2, varscan2
- MYO7B | c.3028G>A p.A1010T | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs763233570, COSV67349373; called by muse, mutect2, varscan2
- MYO9A | c.6293G>A p.R2098Q | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1306237855; called by muse, mutect2, varscan2
- NAA35 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 88/274 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV64485749; called by muse, mutect2, varscan2
- NBAS | c.3010C>T p.R1004* | Nonsense Mutation (SNP) | VAF 26/153 reads (17%) | catalogued as rs780108348, CM157039, COSV55743357; called by muse, mutect2, varscan2
- NCKAP5L | c.3571C>T p.R1191W | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs779317201, COSV100259357; called by muse, mutect2, varscan2
- NCLN | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs778733140; called by muse, mutect2, varscan2
- NCOR1 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 85/219 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs778056591, COSV99250208; called by muse, mutect2, varscan2
- NDOR1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs894858978; called by muse, mutect2
- NDUFS1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); catalogued as rs137994727; called by muse, mutect2, varscan2
- NEB | c.8071C>T p.R2691C | Missense Mutation (SNP) | VAF 138/331 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202044707; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEURL1B | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63940064; called by muse, mutect2, varscan2
- NEUROD6 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 105/326 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1342645399, COSV51769921; called by muse, mutect2, varscan2
- NFYC | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58127870; called by muse, mutect2, varscan2
- NINL | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs369528838, COSV54007058; called by muse, mutect2, varscan2
- NLGN4X | c.1478T>G p.V493G | Missense Mutation (SNP) | VAF 14/375 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52007447; called by muse, mutect2
- NLK | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV69407889; called by muse, mutect2, varscan2
- NMUR1 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs752125596; called by muse, mutect2, varscan2
- NOC4L | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 58/268 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs372807012; called by muse, mutect2, varscan2
- NOL8 | c.2828A>G p.D943G | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV62637396; called by muse, mutect2, varscan2
- NOTCH3 | c.4946C>T p.A1649V | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54632438; called by muse, mutect2, varscan2
- NOTCH3 | c.1522G>A p.V508M | Missense Mutation (SNP) | VAF 153/377 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as rs755398328, COSV54646331; called by muse, mutect2, varscan2
- NR1H3 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 111/320 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.182); catalogued as rs761873817, COSV101269779; called by muse, mutect2, varscan2
- NR3C1 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 93/268 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51544844; called by muse, mutect2, varscan2
- NRXN2 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 103/239 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1047822230, COSV99634709; called by muse, mutect2, varscan2
- NTM | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 83/224 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.576); catalogued as rs1289145335, COSV100868674, COSV66178113; called by mutect2, varscan2
- NUAK2 | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as rs138419867, COSV100904132; called by muse, mutect2
- NUDT8 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363006677, COSV56875152; called by muse, mutect2
- NUMBL | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs968366015; called by muse, mutect2, varscan2
- NUP214 | c.3058C>T p.R1020C | Missense Mutation (SNP) | VAF 96/335 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140330621; called by muse, mutect2, varscan2
- NUP93 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs770006120, COSV100360195; called by muse, mutect2, varscan2
- OAS3 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 138/323 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs374998171; called by muse, mutect2, varscan2
- OBSCN | c.19913A>C p.N6638T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1558416550, COSV62363221; called by muse, mutect2, varscan2
- OGA | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); catalogued as COSV100761926; called by muse, mutect2, varscan2
- OGDH | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753118358, COSV56055165; called by muse, mutect2, varscan2
- OGDHL | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.426); catalogued as rs772306801, COSV65101628; called by muse, mutect2
- OGFOD3 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 125/297 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.202); catalogued as rs778685999, COSV57341326; called by muse, mutect2, varscan2
- OR10G2 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as rs149827969; called by muse, mutect2
- OR10S1 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs964797437; called by muse, mutect2, varscan2
- OR1L6 | c.443A>G p.D148G (on ENST00000373684; = p.D112G on NM_001004453.2) | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1246502205, COSV59028607; called by muse, mutect2
- OR2G6 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs143730398, COSV58574053; called by muse, mutect2
- OR4C13 | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.013); catalogued as COSV73648956; called by muse, mutect2
- OR4C6 | c.158T>G p.L53R | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58605272; called by muse, mutect2
- OR5AR1 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs754489483, COSV57253574; called by muse, mutect2, varscan2
- OR8K3 | c.169A>C p.T57P | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as rs1393565412; called by muse, mutect2, varscan2
- OR9I1 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV56927630; called by muse, mutect2, varscan2
- OS9 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs374016366; called by muse, mutect2, varscan2
- OSBP2 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 41/310 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as rs371214985; called by muse, mutect2, varscan2
- OSBPL6 | c.2551G>A p.A851T | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs750401056; called by muse, mutect2, varscan2
- OTUD7A | c.1721C>T p.S574L (on ENST00000307050 / NM_001382637.1; = p.S567L on NM_130901.3) | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV61042794; called by muse, mutect2
- P2RY4 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as rs778595672; called by muse, mutect2, varscan2
- PALD1 | c.1990G>A p.G664S | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as rs1233709446; called by muse, mutect2, varscan2
- PAMR1 | c.1684G>A p.A562T (on ENST00000619888 / NM_001001991.3; = p.A579T on NM_015430.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144470075; called by muse, mutect2, varscan2
- PAPPA2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs1189516453, COSV62777056; called by muse, mutect2
- PBRM1 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 70/171 reads (41%) | catalogued as COSV56276994; called by muse, mutect2, varscan2
- PCBP2 | c.914G>A p.R305H (on ENST00000439930 / NM_001128911.2; = p.R306H on NM_005016.6) | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV63727838; called by muse, mutect2, varscan2
- PCDHA1 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 11/291 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.163); catalogued as rs1554117857, COSV65374618; called by muse, mutect2
- PCDHA11 | c.1667A>T p.D556V | Missense Mutation (SNP) | VAF 28/730 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100252854; called by muse, mutect2
- PCDHA13 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.027); catalogued as COSV56496063; called by muse, mutect2, varscan2
- PCDHA6 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); catalogued as COSV65350771; called by muse, mutect2, varscan2
- PCDHB12 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 45/335 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.509); catalogued as rs1262281135, COSV53398785, COSV53399160; called by muse, mutect2, varscan2
- PCDHB13 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 91/311 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.488); catalogued as rs1554287752, COSV53399800; called by muse, mutect2, varscan2
- PCDHB14 | c.1960G>C p.A654P | Missense Mutation (SNP) | VAF 76/606 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV99505596; called by muse, varscan2
- PCDHB5 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); catalogued as rs781958932, COSV50647148; called by muse, mutect2, varscan2
- PCDHB6 | c.332A>C p.N111T | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.385); catalogued as COSV99170196; called by muse, mutect2, varscan2
- PCDHGA10 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as rs1450829111, COSV54009638; called by muse, mutect2, varscan2
- PCDHGA3 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 146/494 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs1465495058, COSV54003792; called by muse, mutect2, varscan2
- PCDHGA8 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 238/455 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53947068, COSV53978229; called by muse, mutect2, varscan2
- PCNT | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 71/355 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs761787113, COSV99053884; called by muse, mutect2, varscan2
- PCSK5 | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 36/564 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs558773600; called by muse, mutect2
- PCSK7 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141025136, COSV104414013; called by muse, mutect2, varscan2
- PDE10A | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100604587; called by muse, mutect2, varscan2
- PDE6B | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs776099625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDGFRB | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs759436020, COSV99940740, COSV99940906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDILT | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 136/325 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1191219964; called by muse, mutect2, varscan2
- PDK4 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.675); catalogued as rs1379561937; called by muse, mutect2
- PDPR | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 98/254 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs374988246; called by muse, mutect2, varscan2
- PDS5B | c.865C>A p.R289S | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59728725; called by muse, mutect2
- PDYN | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 130/317 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1028619685; called by muse, varscan2
- PDZRN3 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 153/363 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs368761158; called by muse, mutect2, varscan2
- PEBP4 | c.261C>T p.G87= | Splice Region (SNP) | VAF 24/282 reads (9%) | catalogued as rs376118303, COSV99835206; called by muse, mutect2
- PFKM | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs769512330; called by muse, mutect2, varscan2
- PGAM5 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs774830624; called by muse, mutect2, varscan2
- PGS1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773644712, COSV53143678; called by muse, mutect2, varscan2
- PHF12 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as rs758419622, COSV52020274; called by muse, mutect2, varscan2
- PHTF2 | c.727G>A p.V243I (on ENST00000248550 / NM_001366089.1; = p.V205I on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs61998250; called by muse, mutect2, varscan2
- PIAS3 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs781998989; called by muse, mutect2, varscan2
- PIGT | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.426); catalogued as rs757699605; called by muse, mutect2, varscan2
- PITPNC1 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 95/338 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as rs749876449, COSV55451806; called by muse, mutect2, varscan2
- PIWIL2 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs529353152, COSV63253505, COSV63254414; called by muse, mutect2, varscan2
- PKD1 | c.11545G>A p.A3849T (on ENST00000262304 / NM_001009944.3; = p.A3848T on NM_000296.4) | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as CD1412769; called by muse, mutect2, varscan2
- PKD1 | c.5597T>G p.L1866R | Missense Mutation (SNP) | VAF 83/693 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51915763; called by muse, mutect2, varscan2
- PKD1 | c.3796C>T p.R1266W | Missense Mutation (SNP) | VAF 156/477 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs376754657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCB4 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs758517534; called by muse, mutect2, varscan2
- PLCE1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 213/527 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs767766247, COSV53338884; called by muse, mutect2, varscan2
- PLEC | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.413); catalogued as rs782145378; called by muse, mutect2
- PLEKHG4 | c.2833C>T p.R945C | Missense Mutation (SNP) | VAF 19/317 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs916768388; called by muse, mutect2
- PLEKHG6 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs373302901; called by muse, mutect2, varscan2
- PLEKHH1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs201438923; called by muse, mutect2, varscan2
- PLEKHM1 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs577278828; called by muse, mutect2, varscan2
- PLIN4 | c.2398G>A p.V800I (on ENST00000301286; = p.V815I on NM_001367868.2) | Missense Mutation (SNP) | VAF 108/580 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.478); catalogued as rs200600446, COSV56687279, COSV56698767; called by muse, varscan2
- PLOD1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as rs148510973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLPPR2 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1314416911; called by muse, mutect2, varscan2
- PLPPR5 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs368162905, COSV99587127; called by muse, mutect2, varscan2
- PNMA2 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 71/309 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs371830737; called by muse, mutect2, varscan2
- PODN | c.1546C>T p.R516* (on ENST00000395871; = p.R468* on NM_153703.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 78/168 reads (46%) | catalogued as rs746291140; called by muse, mutect2
- POLA1 | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs762824656, COSV66887675; called by muse, mutect2, varscan2
- POLE | c.5885A>G p.E1962G | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs764022756; called by muse, varscan2
- POLR3D | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.154); catalogued as rs766476082; called by muse, mutect2, varscan2
- POM121 | c.826G>A p.A276T (on ENST00000434423; = p.A11T on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/526 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.596); catalogued as rs182888856; called by muse, mutect2
- POR | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 121/329 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs369924019; called by muse, varscan2
- PPL | c.2975A>G p.Y992C | Missense Mutation (SNP) | VAF 117/401 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1370186827; called by muse, mutect2, varscan2
- PPP1R18 | c.1775T>A p.L592Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV51294710; called by muse, mutect2, varscan2
- PPP1R3F | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs782769164, COSV50019286; called by muse, mutect2, varscan2
- PRAMEF7 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 69/442 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.071); catalogued as rs1410587983, COSV100435171; called by mutect2, varscan2
- PREP | c.1739C>T p.P580L (on ENST00000369110; = p.P646L on NM_002726.5) | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1249254287; called by muse, mutect2, varscan2
- PRKAR1B | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs759197351; called by muse, mutect2, varscan2
- PRKN | c.610A>G p.T204A | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV100632030; called by muse, mutect2, varscan2
- PRLHR | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs1564810988, COSV53303088; called by muse, mutect2, varscan2
- PRPF8 | c.4252C>T p.R1418* | Nonsense Mutation (SNP) | VAF 166/430 reads (39%) | catalogued as COSV59267791; called by muse, mutect2, varscan2
- PRRC2C | c.4055G>A p.R1352H (on ENST00000367742; = p.R1350H on NM_015172.4) | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs142373462; called by muse, mutect2, varscan2
- PSCA | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs372257395; called by muse, mutect2, varscan2
- PSMG2 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1257030998; called by muse, mutect2, varscan2
- PTGER3 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as COSV100138502, COSV60695422; called by muse, mutect2
- PTK2 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs775267050; called by muse, mutect2, varscan2
- PTPN23 | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771582644; called by muse, mutect2, varscan2
- PTPN6 | c.1265T>C p.V422A | Missense Mutation (SNP) | VAF 34/407 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1555149024; called by muse, mutect2
- PTPRD | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 27/366 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV100643142; called by muse, mutect2
- PTPRS | c.3875C>T p.A1292V | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53617908; called by muse, mutect2, varscan2
- PTPRT | c.2075A>C p.N692T | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV62007844; called by muse, mutect2, varscan2
- PUS7L | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149316041, COSV100786438, COSV61262561; called by muse, mutect2, varscan2
- PXDNL | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV62476741; called by muse, mutect2
- QSOX1 | c.622T>C p.S208P | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.733); catalogued as COSV100852782; called by muse, varscan2
- RACGAP1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs372329078; called by muse, mutect2, varscan2
- RAD50 | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs535261113, COSV54756639; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RALGDS | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 146/564 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs550664081, COSV64426981, COSV64429833; called by muse, mutect2, varscan2
- RARRES1 | c.509A>C p.N170T | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV52962406; called by muse, mutect2
- RASAL3 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52992195; called by muse, mutect2, varscan2
- RBM5 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 94/215 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as rs138305114; called by muse, mutect2, varscan2
- RBMXL3 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 74/110 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.522); catalogued as rs912004716; called by muse, mutect2, varscan2
- RBP3 | c.3029G>A p.R1010H | Missense Mutation (SNP) | VAF 38/315 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs149031179; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBSN | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 110/286 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs144261272; called by muse, mutect2, varscan2
- REEP1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1351359618, COSV51257608; called by muse, mutect2, varscan2
- RELN | c.6817G>C p.G2273R | Missense Mutation (SNP) | VAF 153/605 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV100633535; called by muse, mutect2, varscan2
- REXO4 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370225194; called by muse, mutect2, varscan2
- RGS12 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 118/243 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs768337709, COSV60907521; called by muse, mutect2, varscan2
- RNF10 | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 43/101 reads (43%) | catalogued as rs774506367, COSV58048663; called by muse, mutect2, varscan2
- RNF167 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs777022842; called by muse, mutect2, varscan2
- RNF20 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 59/353 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66355632; called by muse, mutect2, varscan2
- ROBO1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs765000690, COSV101458240, COSV71395171; called by muse, mutect2, varscan2
- RP1L1 | c.5299G>A p.A1767T | Missense Mutation (SNP) | VAF 16/490 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV66754057; called by muse, mutect2
- RPA4 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs144423256; called by muse, mutect2, varscan2
- RPF2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as rs1436629810, COSV64369684; called by muse, mutect2, varscan2
- RPL23 | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.248); catalogued as COSV55559694; called by muse, mutect2
- RPS2 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as rs369095700; called by muse, mutect2, varscan2
- RSC1A1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs748304784; called by muse, mutect2, varscan2
- RSPH9 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573327402, COSV64664009; called by mutect2, varscan2
- RTKN | c.284C>T p.A95V (on ENST00000272430 / NM_001015055.2; = p.A82V on NM_033046.2) | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.391); catalogued as rs542691717; called by muse, mutect2, varscan2
- RTL1 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs762024883, COSV66017376; called by muse, mutect2, varscan2
- RTN1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 131/335 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs772853362, COSV50720293, COSV50737223; called by muse, mutect2, varscan2
- RUNX3 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768608661; called by muse, mutect2, varscan2
- S100Z | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV58256614; called by muse, mutect2, varscan2
- SAFB | c.2038C>T p.R680C | Missense Mutation (SNP) | VAF 44/454 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1289784656; called by muse, mutect2
- SAG | c.503T>A p.I168N | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as rs753195608; called by muse, mutect2, varscan2
- SALL4 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 104/260 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs371371697, COSV53850705; called by muse, mutect2, varscan2
- SAMD3 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs763920331, COSV63717021; called by muse, mutect2
- SARDH | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1028521564; called by muse, mutect2, varscan2
- SBF1 | c.3934C>T p.R1312C | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs567286954; called by muse, mutect2, varscan2
- SBK2 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs546747792; called by muse, varscan2
- SCN4A | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1403270355, COSV71125724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN8A | c.5522G>A p.R1841H | Missense Mutation (SNP) | VAF 108/302 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61990629; called by muse, mutect2, varscan2
- SCNN1G | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 180/397 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs369647146; called by muse, mutect2, varscan2
- SEL1L | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 54/117 reads (46%) | catalogued as rs777962520, COSV100377853; called by muse, mutect2, varscan2
- SEPTIN11 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs773831318, COSV53584149; called by muse, mutect2, varscan2
- SERPINE1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 58/744 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.259); catalogued as rs767250801, COSV56168706; called by muse, mutect2
- SFRP4 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as rs769681617; called by muse, mutect2, varscan2
- SGK2 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1200346658, COSV58313159; called by muse, mutect2
- SH3BP4 | c.1984C>T p.L662F | Missense Mutation (SNP) | VAF 76/291 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1216581757, COSV60644201; called by muse, mutect2, varscan2
- SH3GL1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 174/434 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs150815092; called by muse, mutect2, varscan2
- SHANK1 | c.6391G>A p.A2131T | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs757609780, COSV53259950; called by muse, mutect2, varscan2
- SHANK1 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53247809; called by muse, mutect2, varscan2
- SHANK3 | c.2393A>G p.D798G | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as rs1364922217; called by muse, mutect2
- SHROOM1 | c.1453A>G p.T485A | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1222064783; called by muse, mutect2, varscan2
- SI | c.3414A>C p.Q1138H | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52271481; called by muse, mutect2, varscan2
- SIRPA | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as rs146048438; called by muse, mutect2, varscan2
- SKP2 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.821); catalogued as COSV57041257; called by muse, mutect2, varscan2
- SLC12A3 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs374055486; called by muse, mutect2, varscan2
- SLC12A3 | c.2965C>A p.L989M (on ENST00000563236 / NM_001126108.2; = p.L998M on NM_000339.3) | Missense Mutation (SNP) | VAF 112/393 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs764119190; called by muse, mutect2, varscan2
- SLC12A5 | c.1432G>A p.A478T (on ENST00000454036 / NM_001134771.2; = p.A455T on NM_020708.5) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as rs992510978, COSV54797716; called by muse, mutect2
- SLC12A9 | c.1619A>C p.N540T | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs761044570; called by muse, mutect2, varscan2
- SLC22A11 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs756887929, COSV57254704; called by muse, mutect2
- SLC27A6 | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 105/211 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.034); catalogued as COSV52483564; called by muse, mutect2, varscan2
- SLC2A6 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 32/466 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs782466605, COSV99390116; called by muse, mutect2
- SLC34A3 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 75/369 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs374826755; called by muse, mutect2, varscan2
- SLC45A1 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762771884; called by muse, mutect2, varscan2
- SLC45A1 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 188/475 reads (40%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.896); catalogued as rs765438459; called by muse, mutect2, varscan2
- SLC47A2 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 107/404 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs147034810, COSV57627014; called by muse, mutect2, varscan2
- SLC5A6 | c.1759G>A p.G587S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764448030, COSV100143422; called by muse, mutect2, varscan2
- SLC6A12 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755704366, COSV62885126; called by muse, mutect2, varscan2
- SLC8A3 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772541433, COSV63521290; called by muse, mutect2, varscan2
- SLC8B1 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs145132011; called by muse, mutect2, varscan2
- SLIT3 | c.2635C>T p.P879S | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs768977715, COSV60596990; called by muse, mutect2, varscan2
- SLITRK2 | c.820A>G p.R274G | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.069); catalogued as COSV59427704; called by muse, mutect2
- SMARCD3 | c.839G>A p.R280H (on ENST00000262188 / NM_001003801.2; = p.R267H on NM_003078.4) | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs139896646; called by muse, mutect2, varscan2
- SMPD4 | c.1186G>A p.A396T (on ENST00000409031 / NM_017951.4; = p.A367T on NM_017751.4) | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.059); catalogued as rs765809356, COSV100302257; called by muse, mutect2, varscan2
- SND1 | c.2395G>A p.A799T | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1490621481, COSV61241701; called by muse, mutect2
- SNW1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs151149018; called by muse, mutect2, varscan2
- SNX27 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64326959; called by muse, mutect2, varscan2
- SOGA3 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV64109137; called by muse, mutect2, varscan2
- SOHLH1 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 91/322 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372516323; called by muse, mutect2, varscan2
- SOWAHA | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1019088796; called by muse, mutect2, varscan2
- SPACA3 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as rs765816585; called by muse, mutect2, varscan2
- SPAG11B | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1172473731; called by muse, mutect2
- SPATA31A1 | c.3746A>C p.N1249T | Missense Mutation (SNP) | VAF 64/1404 reads (5%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.73); catalogued as COSV66533301; called by muse, mutect2
- SPATA31A6 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 55/892 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs774601556; called by muse, mutect2
- SPATA31D1 | c.3743A>G p.D1248G | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs762464998; called by muse, varscan2
- SPDYE5 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 227/805 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as rs587625794, COSV71596460; called by muse, mutect2, varscan2
- SPECC1 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1052334949; called by muse, mutect2, varscan2
- SRCAP | c.4034G>A p.R1345H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.048); catalogued as rs780477358; called by muse, mutect2, varscan2
- SRGN | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 45/376 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs529263420; called by muse, mutect2, varscan2
- SRPX2 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 89/157 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs750566351, COSV65933317; called by muse, mutect2, varscan2
- SSH3 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 97/247 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs748684124; called by muse, mutect2, varscan2
- ST14 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs147508411, COSV99598941; called by muse, mutect2, varscan2
- ST3GAL4 | c.856G>A p.A286T (on ENST00000392669 / NM_001254758.1; = p.A282T on NM_006278.3) | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs550860098, COSV99917717; called by muse, mutect2
- STARD13 | c.1874C>T p.T625M (on ENST00000336934 / NM_001243476.3; = p.T507M on NM_052851.3) | Missense Mutation (SNP) | VAF 71/91 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275205577; called by muse, mutect2, varscan2
- STPG3 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.382); catalogued as rs778225662; called by muse, mutect2, varscan2
- STRC | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs761913900; called by mutect2, varscan2
- STRIP2 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs753138026; called by muse, mutect2, varscan2
- STXBP5 | c.2459C>T p.T820M (on ENST00000321680 / NM_001127715.2; = p.T784M on NM_139244.4) | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1308870876; called by muse, mutect2, varscan2
- SUGP2 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 109/395 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs759499277, COSV58255974; called by muse, mutect2, varscan2
- SUOX | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs575678301; called by muse, mutect2, varscan2
- SURF6 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 105/434 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs995584040; called by muse, mutect2, varscan2
- SYBU | c.547C>T p.R183W (on ENST00000276646 / NM_001099754.2; = p.R182W on NM_017786.6) | Missense Mutation (SNP) | VAF 25/413 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761014767; called by muse, mutect2
- SYNCRIP | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.219); catalogued as rs759806623; called by muse, mutect2, varscan2
- SYNE3 | c.2485G>A p.A829T | Missense Mutation (SNP) | VAF 65/239 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs757497360, COSV62078767; called by muse, mutect2, varscan2
- SYNE3 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs201173477, COSV100515512; called by muse, mutect2, varscan2
- SYT16 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760675924, COSV70855812; called by muse, mutect2, varscan2
- SYT3 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.028); catalogued as rs768053715, COSV100144288, COSV58896996; called by muse, mutect2, varscan2
- SZT2 | c.9562C>T p.R3188W (on ENST00000634258 / NM_001365999.1; = p.R3131W on NM_015284.4) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758178091, COSV100981329; called by muse, mutect2, varscan2
- TAC3 | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 77/525 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs1254512108; called by muse, mutect2, varscan2
- TACC2 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs143121367; called by muse, mutect2, varscan2
- TACSTD2 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.195); catalogued as rs777336655; called by muse, varscan2
- TAF4 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 80/160 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1217655784, COSV53343349; called by muse, mutect2, varscan2
- TAGAP | c.2131C>T p.R711* | Nonsense Mutation (SNP) | VAF 20/122 reads (16%) | catalogued as COSV57851534; called by muse, mutect2, varscan2
- TAMM41 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs146141760; called by muse, mutect2, varscan2
- TANC2 | c.3601C>T p.R1201C | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs901125104, COSV67333964; called by muse, varscan2
- TBC1D25 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1556986194, COSV100952260; called by muse, mutect2, varscan2
- TBC1D4 | c.3149C>T p.S1050L | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs767493446, COSV66490398; called by muse, mutect2, varscan2
- TBKBP1 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as rs1212399875; called by muse, varscan2
- TBL1X | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV54275958; called by muse, mutect2
- TBX5 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 167/364 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs145784562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TECPR1 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as rs745619481; called by muse, mutect2, varscan2
- TEDC2 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1054439070; called by muse, mutect2, varscan2
- TENM4 | c.7018G>A p.D2340N | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1229398455; called by muse, mutect2, varscan2
- TEX13A | c.1044del p.H350Tfs*3 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | catalogued as COSV61186225; called by mutect2, pindel
- TFCP2 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs369701126, COSV56931301; called by muse, mutect2, varscan2
- TGFB1I1 | c.778G>A p.A260T (on ENST00000394863 / NM_001042454.3; = p.A243T on NM_015927.4) | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs868502875; called by muse, mutect2, varscan2
- TGFB2 | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.61); catalogued as rs1187360350; called by muse, mutect2, varscan2
- TGM1 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1000189283, COSV52864349; called by muse, mutect2, varscan2
- THAP8 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs770198368; called by muse, mutect2, varscan2
- THSD7A | c.3934C>T p.R1312* | Nonsense Mutation (SNP) | VAF 67/184 reads (36%) | catalogued as rs777727562, COSV69855816; called by muse, mutect2, varscan2
- TIA1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 35/150 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as rs745767818; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMCC2 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV58006364; called by muse, mutect2, varscan2
- TMEM245 | c.1951G>T p.A651S | Missense Mutation (SNP) | VAF 99/335 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV101002271; called by muse, mutect2, varscan2
- TMEM53 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 93/203 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs750410092; called by muse, mutect2, varscan2
- TMEM63A | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376648031; called by muse, mutect2, varscan2
- TMEM71 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 166/474 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as rs750698828, COSV63457112; called by muse, mutect2, varscan2
- TMPRSS2 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1288985267; called by muse, mutect2
- TMPRSS6 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 31/479 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs146291916; called by muse, mutect2
- TMPRSS9 | c.2600C>T p.A867V (on ENST00000648592; = p.A833V on NM_182973.2) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764762215, COSV53115310; called by muse, mutect2, varscan2
- TNC | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs749140505; called by muse, mutect2, varscan2
- TNFRSF10A | c.1123G>A p.V375M | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777239727, COSV99646159; called by muse, mutect2, varscan2
- TNN | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs151048294, COSV53426279; called by muse, mutect2, varscan2
- TNR | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs984032476, COSV54872423, COSV54884485; called by muse, mutect2
- TNR | c.1040A>G p.D347G | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as COSV99692294; called by muse, mutect2
- TNRC18 | c.6784G>A p.V2262M | Missense Mutation (SNP) | VAF 65/284 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758118578, COSV100078995; called by muse, mutect2, varscan2
- TONSL | c.2801G>A p.R934Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1564729049; called by muse, mutect2, varscan2
- TOP1MT | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as rs1325634219, COSV61317615; called by muse, mutect2
- TRAM1L1 | c.578T>C p.I193T | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV60293231; called by muse, mutect2, varscan2
- TRAPPC12 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1251785709; called by muse, mutect2
- TRAPPC8 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV99350565; called by muse, mutect2
- TRMT2A | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 114/288 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs769265960; called by muse, mutect2, varscan2
- TSC1 | c.2116C>T p.R706C | Missense Mutation (SNP) | VAF 124/584 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53767903; called by muse, mutect2, varscan2
- TSPAN11 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as COSV53816465; called by muse, mutect2
- TSPAN33 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as rs768190545, COSV56825609; called by muse, mutect2, varscan2
- TSR1 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770219560; called by muse, mutect2, varscan2
- TTC16 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 94/468 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.222); catalogued as rs1476641345; called by muse, mutect2, varscan2
- TTC3 | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs749136748, COSV61286787; called by muse, mutect2, varscan2
- TTLL2 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs11540664; called by muse, mutect2, varscan2
- TTLL4 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs766751761, COSV51439904; called by muse, mutect2, varscan2
- TTYH3 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs895425490, COSV51859679, COSV99350123; called by muse, mutect2, varscan2
- TUBA3D | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.044); catalogued as rs756357409; called by muse, mutect2, varscan2
- TYW1B | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 95/348 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781996061, COSV100646494; called by muse, mutect2, varscan2
- UAP1L1 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs749801324; called by muse, mutect2, varscan2
- UBAP2 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs751853002, COSV62547255; called by muse, mutect2, varscan2
- UBP1 | c.1623A>G p.*541Wext*4 | Nonstop Mutation (SNP) | VAF 9/95 reads (9%) | catalogued as rs142730104; called by muse, mutect2, varscan2
- UBR4 | c.12821G>A p.R4274Q | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV64386606, COSV64389033; called by muse, mutect2, varscan2
- UCMA | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs372826471; called by muse, mutect2, varscan2
- UCP3 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 129/301 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758805473, COSV58368284; called by muse, mutect2, varscan2
- UGT1A6 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs748166510, COSV59385976; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2318C>T p.P773L | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs773470286; called by muse, mutect2, varscan2
- ULK3 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773081225, COSV101475544; called by muse, mutect2, varscan2
- UNC13C | c.6125C>T p.A2042V | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99516786; called by muse, mutect2
- UNC80 | c.8660G>A p.R2887H | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.989); catalogued as rs774199606, COSV55905434; called by muse, mutect2, varscan2
- UNKL | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1177262207; called by muse, mutect2, varscan2
- USP9X | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.395); catalogued as rs867833382, COSV61067071; called by muse, mutect2
- UTRN | c.4588G>A p.A1530T | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771082025, COSV100839462; called by muse, varscan2
- VCAM1 | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as rs533971321; called by muse, mutect2, varscan2
- VCAM1 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs375185009; called by mutect2, varscan2
- VLDLR | c.820+1G>A p.X274_splice | Splice Site (SNP) | VAF 123/431 reads (29%) | catalogued as rs1563758564, COSV66073795; called by muse, mutect2, varscan2
- VNN3 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774659578; called by muse, mutect2, varscan2
- VPS13D | c.3020A>G p.D1007G | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264043419; called by muse, mutect2, varscan2
- VPS33A | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.188); catalogued as rs768777668, COSV57355948; called by muse, mutect2, varscan2
- VPS35 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 158/366 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs779434158; called by muse, mutect2, varscan2
- VWF | c.5542G>A p.V1848M | Missense Mutation (SNP) | VAF 157/356 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as rs376993019, COSV54617546; called by muse, mutect2, varscan2
- WARS2 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 45/369 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.148); catalogued as rs753141532, COSV52477902; called by muse, mutect2, varscan2
- WASH6P | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 106/752 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.294); catalogued as rs762388997; called by muse, varscan2
- WBP1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs534766337, COSV51971528; called by muse, mutect2, varscan2
- WDFY3 | c.8657A>G p.D2886G | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV104399867; called by muse, mutect2, varscan2
- WDFY4 | c.6899G>A p.R2300H | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs537213971, COSV55443362; called by muse, mutect2, varscan2
- WDR33 | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs181571193, COSV100460133; called by muse, mutect2, varscan2
- WFS1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs375904080, CM134079; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- WNK4 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 176/430 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1422885374; called by muse, mutect2, varscan2
- XCR1 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 86/194 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs761821740; called by muse, mutect2, varscan2
- XIRP1 | c.3629C>T p.A1210V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs35573430, COSV61141673; called by muse, mutect2, varscan2
- XIRP1 | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs758869210; called by muse, mutect2, varscan2
- XIRP2 | c.6796T>C p.S2266P (on ENST00000628543; = p.S2441P on NM_152381.6) | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV54682973; called by muse, mutect2
- XIRP2 | c.7816A>G p.T2606A (on ENST00000628543; = p.T2781A on NM_152381.6) | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV54692410; called by muse, mutect2
- XKR5 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.144); catalogued as rs1478483260; called by muse, mutect2
- YWHAB | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.437); catalogued as rs1249701757; called by muse, mutect2, varscan2
- YWHAG | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 115/339 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs776692453, COSV104409986; called by muse, mutect2, varscan2
- ZBED3 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1279311355; called by muse, mutect2, varscan2
- ZBTB34 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs373089625; called by muse, mutect2, varscan2
- ZBTB46 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1336448650, COSV55510351; called by muse, mutect2, varscan2
- ZBTB49 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 133/297 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as rs372045936; called by muse, mutect2, varscan2
- ZBTB5 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV100312978; called by muse, mutect2
1,223 further variants in this file (540 protein-altering or splice-affecting, 480 silent, 203 other) are not listed here.
